Surgical pathology report (de-identified scan), TCGA case TCGA-A2-A0YH, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Walter Reed, specimen TCGA-A2-A0YH-01A (Primary Tumor).

[page 1 of 2]
Chief of

Phone

Fax

CPWSU

Specimen:

Received:

Status:

Spec Type: SURGICAL P

Subm Dr:

OPERATION PERFORMED

DATE:

DOCTOR(S):

PROCEDURE: PARTIAL MASTECTOMY/LUMPECTOMY-AXILLARY NODE DISSECTION

TISSUE REMOVED

- A. LT PARTIAL MASTECTOMY
- B. LT AXILLARY NODE
- C. LT BREAST INFERIOR AND SUPERFICIAL MARGIN

1CD-0-3

Carcinoma, infiltrating duct, nos 8500/3
Site: breast, nos C50.9 1/27/14

GROSS DESCRIPTION

PART A RECEIVED FRESH LABELED [REDACTED] LEFT PARTIAL MASTECTOMY LONG EQUALS LATERAL SHORT EQUALS SUPERIOR, IS AN OVOID PORTION OF YELLOW-PINK FATTY TISSUE MEASURING 7 X 6 X 3.5 CM. THE SPECIMEN IS ORIENTED BY TWO SUTURES AND MARKED AS FOLLOWS: LATERAL ORANGE, MEDIAL RED, SUPERIOR GREEN, INFERIOR BLUE, SUPERFICIAL BLACK, DEEP YELLOW. A LARGE PALPABLE MASS IS FELT WITHIN THE SPECIMEN INFERIOR AND MEDIALY. SECTIONING REVEALS A ROUNDED PINK-TAN MASS MEASURING 2.4 X 2.2 X 2.7 CM IN GREATEST DIMENSIONS. THIS APPROACHES THE SUPERFICIAL, DEEP AND INFERIOR MARGINS, GROSSLY EXTENDING TO WITHIN 0.2 CM OF EACH OF THESE. IT IS GREATER THAN 1 CM FROM THE OTHER MARGINS. THE SPECIMEN CONSISTS OF PINK-TAN FIBROUS TISSUE IN THE MEDIAL ASPECT OF THE SPECIMEN AND YELLOW FATTY TISSUE MORE Laterally. A RIBBON CLIP IS IDENTIFIED WITHIN THIS LESION. SECTIONS ARE SUBMITTED AS FOLLOWS: A1--REPRESENTATIVE PERPENDICULAR MEDIAL MARGIN, A2--REPRESENTATIVE PERPENDICULAR LATERAL MARGIN, A3--TUMOR (MIRROR IMAGE TO PROTOCOL), A4--TUMOR AND INFERIOR MARGIN (MIRROR IMAGE TO PROTOCOL), A5--LESION AND INFERIOR MARGIN, A6--TUMOR AND SUPERFICIAL MARGIN, A7--TUMOR AND DEEP MARGIN. NOTE THAT A5 THROUGH A6 IS ONE FULL CROSS-SECTION OF LESION, WITH A6 MIRROR IMAGE TO TISSUE TAKEN PER PROTOCOL. A8--TISSUE AND SUPERFICIAL MARGIN CORRESPONDING TO THE TUMOR IN A3 (MIRROR IMAGE TO PROTOCOL TISSUE), A9--TISSUE TO INCLUDE THE DEEP AND SUPERIOR MARGINS CORRESPONDING TO THE CROSS-SECTION DEPICTED IN A5 THROUGH 7, A10--THE CORRESPONDING DEEP MARGIN TO THE TUMOR TAKEN IN A3, A11--THE LATERAL ASPECT OF THE TUMOR TO INCLUDE THE INFERIOR SUPERFICIAL MARGIN.

PART B RECEIVED FRESH LABELED [REDACTED] LEFT AXILLARY NODE DISSECTION, IS A PORTION OF YELLOW-RED FATTY TISSUE MEASURING 10 X 7.6 X 4.8 CM IN GREATEST DIMENSIONS. THIS IS EXAMINED FOR LYMPH NODES WHICH ARE THEN SUBMITTED AS FOLLOWS: B1--GROSSLY UNREMARKABLE LYMPH NODE, B2--SECTION OF GROSSLY POSITIVE LYMPH NODE, B3--SECTION OF GROSSLY POSITIVE LYMPH NODE WITH COIL CLIP. NOTE: SPECIMENS B1 THROUGH 3 ARE MIRROR IMAGES TO PROTOCOL SECTIONS. B4 AND 5--ONE NODE TOTAL, B6--TWO NODES EACH BISECTED, B7--TWO NODES EACH BISECTED, B8--THREE NODES EACH BISECTED, B9--THREE NODES, B10--ONE NODE BISECTED, B11--ONE NODE BISECTED, B12--ONE NODE BISECTED.

AFTER A SHORT TIME OF ACETIC FORMALIN FIXATION, ADDITIONAL NODES ARE

[page 2 of 2]
Chief of Pathology

Phone

Fax

Patient: [REDACTED]

(Continued)

Specimen:

Received:

Status:

Spec Type: SURGICAL P

Subm Dr:

GROSS DESCRIPTION

(Continued)

IDENTIFIED AND SUBMITTED AS FOLLOWS: B13--ONE NODE BISECTED, B14--FIVE NODES, B15--THREE NODES EACH BISECTED, B16--TWO NODES EACH BISECTED.

PART C RECEIVED LABELED [REDACTED] LEFT BREAST INFERIOR AND SUPERFICIAL MARGIN STITCH AT NEW MARGIN, IS AN OVOID PORTION OF YELLOW-PINK FATTY TISSUE MEASURING 6.4 X 5.4 X 1.1 CM. SUTURE DENOTES A NEW MARGIN. THIS SIDE IS MARKED WITH BLUE INK WITH A PERIMETER OF BLACK INK. THE SPECIMEN IS SECTIONED AND ENTIRELY SUBMITTED LABELED C1 THROUGH 10.

PATH PROCEDURES

PROCEDURES:

88307/3, A BLK/11, B BLK/16, C BLK/10

FINAL DIAGNOSIS

PART A LEFT PARTIAL MASTECTOMY: IN SITU AND POORLY DIFFERENTIATED INFILTRATING DUCT CARCINOMA, NUCLEAR GRADE III/III WITH A HIGH MITOTIC INDEX. THE INVASIVE TUMOR IS 2.4 CM IN MAXIMUM MICROSCOPIC DIMENSION. A 0.9 CM FOCUS OF DUCT CARCINOMA IN SITU OF THE MICROPAPILLARY AND COMEDOCARCINOMA TYPES IS PRESENT ADMIXED WITH AND ADJACENT TO THE INVASIVE TUMOR. DUCT CARCINOMA IN SITU IS PRESENT 1 MM FROM THE SUPERFICIAL MARGIN, WITH INVASIVE CARCINOMA 1.5 MM FROM THE SUPERFICIAL MARGIN. INVASIVE CARCINOMA IS ALSO PRESENT IN A MICROSCOPIC SATELLITE NODULE 1 MM FROM THE DEEP MARGIN. THE INFERIOR MARGIN IS CLEAR BY A DISTANCE OF 3 MM. THE SUPERIOR, MEDIAL, AND LATERAL MARGINS ARE ALL CLEAR OF TUMOR BY DISTANCES EXCEEDING 1 CM. THERE IS A SMALL FOCUS OF ATYPICAL DUCT HYPERPLASIA 3 MM FROM THE MEDIAL MARGIN.

PART B LEFT AXILLARY LYMPH NODE DISSECTION: METASTATIC CARCINOMA IDENTIFIED IN 5 OF 28 AXILLARY LYMPH NODES.

PART C LEFT BREAST SUPERFICIAL AND INFERIOR MARGIN, REEXCISION: FRAGMENTS OF BENIGN FATTY BREAST TISSUE AND A MICROSCOPIC FOCUS OF INFILTRATING DUCT CARCINOMA. THIS 1 MM FOCUS OF CARCINOMA HAS A CAUTERIZED MARGIN AND IS SEPARATE FROM THE ADJACENT ADIPOSE TISSUE. THE AREA IS NOT INKED, BUT ITS RELATIONSHIP TO THE MARGIN CANNOT BE ACCURATELY DETERMINED BECAUSE IT IS NOT ATTACHED TO THE INKED MARGIN PORTION OF THE SPECIMEN. THIS FOCUS OF TUMOR IS PRESENT IN 1 OF 10 TISSUE BLOCKS (BLOCK C10).

CODE

HPOAA Discrepancy		
Case if (circle):	QUALIFIED	CRASHED

1

Signed

(prelim.)

Source: NCI Genomic Data Commons file 3a514b6a-fc8e-42cb-b363-7d43e2257755 (TCGA-A2-A0YH.0C344CD7-6FAB-462B-9A8E-75B720F2D626.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).